Somatic mutation profile of tumor specimen 0D8ODV from CCDI case PBBHVH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.1 years (4,768 days).
Specimen 0D8ODV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a27d4a1b-1f8b-4f47-8da1-ce9d0327b8c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8ODU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf1d0e7e-c80a-4065-b190-4a89a0fd00ce

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/359 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 21/750 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- NF1 | c.7312T>A p.Y2438N (on ENST00000358273 / NM_001042492.3; = p.Y2417N on NM_000267.3) | Missense Mutation (SNP) | VAF 145/518 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF560 | c.723G>A p.T241= | Silent (SNP) | VAF 108/470 reads (23%) | catalogued as rs572421683, COSV56866666; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
